Somatic mutation profile of tumor specimen TCGA-5L-AAT1-01A (aliquot TCGA-5L-AAT1-01A-12D-A41F-09) from TCGA case TCGA-5L-AAT1, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 63.6 years (23,225 days).
Specimen TCGA-5L-AAT1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ae76261-4ca4-4ebe-9ee0-4e81d5dce60e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5L-AAT1-10A (Blood Derived Normal), aliquot TCGA-5L-AAT1-10A-01D-A41F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48920d9e-ff0e-4126-8c10-e52b2baed8cf

The open-access MAF lists 1,290 somatic variants for this specimen: 947 protein-altering or splice-affecting, 310 silent, 33 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 811, Silent 310, Nonsense Mutation 111, Splice Site 15, RNA 12, Intron 8, 5'UTR 6, 5'Flank 4, 3'UTR 3, Frame Shift Ins 3, Splice Region 2, Nonstop Mutation 2.

Variants (750 of 1,290; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA3 | c.878T>A p.M293K | Missense Mutation (SNP) | VAF 30/116 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM161496, COSV60515607, COSV60521489; called by muse, mutect2, varscan2
- NF1 | c.1603C>T p.Q535* | Nonsense Mutation (SNP) | VAF 56/163 reads (34%) | catalogued as rs1567843917, CM1512913, COSV62199278; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 29/167 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 44/227 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPM1D | c.1403C>G p.S468* | Nonsense Mutation (SNP) | VAF 15/104 reads (14%) | hotspot (GDC flag); catalogued as rs375975790, COSV59955464, COSV59955889; called by muse, mutect2, varscan2
- UBA5 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as rs886039757, COSV53904621; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AACS | c.592C>G p.Q198E | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764827940; called by muse, mutect2
- AARS1 | c.2569C>A p.L857I | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99933756; called by muse, mutect2, varscan2
- ABCA13 | c.6922C>G p.L2308V | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as COSV101447170; called by muse, varscan2
- ABCA13 | c.10798G>A p.E3600K | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1294255853, COSV101447172; called by muse, mutect2
- ABCA3 | c.5067C>G p.F1689L | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100069058; called by muse, varscan2
- ABCA8 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as rs368828473, COSV52208810; called by muse, mutect2, varscan2
- ABCA8 | c.1497G>C p.L499F | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99286717; called by muse, mutect2, varscan2
- ABCB4 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1408217402, CM1313633, COSV55942398; called by muse, mutect2, varscan2
- ABCB6 | c.1367C>T p.S456F | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99202492; called by muse, mutect2, varscan2
- ABCD2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752270059, COSV100429415; called by muse, mutect2
- ABCF1 | c.2241G>C p.Q747H (on ENST00000326195 / NM_001025091.2; = p.Q709H on NM_001090.3) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100401024; called by muse, mutect2, varscan2
- ABCG2 | c.1542G>A p.M514I | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs529212191, COSV99420023; called by muse, mutect2, varscan2
- ABHD4 | c.486-1G>C p.X162_splice | Splice Site (SNP) | VAF 21/100 reads (21%) | catalogued as COSV99360606; called by muse, mutect2, varscan2
- AC018630.4 | c.28C>G p.P10A | Missense Mutation (SNP) | VAF 9/104 reads (9%) | PolyPhen benign (0.011); catalogued as COSV101115506; called by muse, mutect2
- ACACB | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.184); catalogued as rs1012906544, COSV100623251; called by muse, mutect2
- ACKR3 | c.414G>T p.M138I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV56021794, COSV56024119; called by muse, mutect2
- ACTBL2 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); catalogued as COSV101379412; called by muse, mutect2, varscan2
- ADAM32 | c.1570C>G p.Q524E | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV99060616; called by muse, mutect2, varscan2
- ADAMTS1 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV53170986; called by muse, mutect2, varscan2
- ADAMTS13 | c.3061C>G p.L1021V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.372); catalogued as COSV100747191; called by muse, mutect2
- ADAMTS16 | c.1409C>A p.S470Y | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs766351634, COSV99942704; called by muse, mutect2, varscan2
- ADAR | c.2821G>C p.E941Q | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99426630; called by muse, mutect2, varscan2
- ADAR | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); catalogued as COSV99426631; called by muse, mutect2
- ADCK2 | c.857C>G p.S286* | Nonsense Mutation (SNP) | VAF 17/110 reads (15%) | catalogued as COSV99301838; called by muse, mutect2, varscan2
- ADCY2 | c.1909C>G p.L637V | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV100603910; called by muse, mutect2, varscan2
- ADCY8 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.206); catalogued as COSV99654023; called by muse, mutect2, varscan2
- ADGRB3 | c.3190C>T p.Q1064* | Nonsense Mutation (SNP) | VAF 26/112 reads (23%) | catalogued as COSV99486663; called by muse, mutect2, varscan2
- ADGRE2 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as COSV100216460; called by muse, mutect2, varscan2
- ADGRL1 | c.2582C>T p.S861L (on ENST00000340736 / NM_001008701.3; = p.S856L on NM_014921.5) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.227); catalogued as rs781100862, COSV61564578; called by muse, mutect2, varscan2
- ADGRL1 | c.1012G>A p.E338K (on ENST00000340736 / NM_001008701.3; = p.E333K on NM_014921.5) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1236774289, COSV100529784; called by muse, mutect2, varscan2
- ADGRV1 | c.16592C>T p.S5531F | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.347); catalogued as rs1291515634, COSV101316414; called by muse, mutect2, varscan2
- ADPRH | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100813364; called by muse, mutect2, varscan2
- ADRA1A | c.495G>C p.W165C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs997765683, COSV99370915; called by muse, mutect2, varscan2
- AEBP1 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs779044302, COSV99788780; called by muse, mutect2, varscan2
- AFF1 | c.1911G>C p.Q637H | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV100321011; called by muse, mutect2, varscan2
- AGPS | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99931672; called by muse, mutect2
- AGRN | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101039049; called by muse, mutect2, varscan2
- AHNAK | c.12868G>C p.E4290Q | Missense Mutation (SNP) | VAF 37/230 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.271); catalogued as rs1292690127, COSV99949314; called by muse, mutect2, varscan2
- AHNAK | c.12429G>A p.M4143I | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV99949317; called by muse, mutect2, varscan2
- AK7 | c.1486+1G>T p.X496_splice | Splice Site (SNP) | VAF 21/262 reads (8%) | catalogued as COSV99967038, COSV99967500; called by muse, mutect2
- AKR1B10 | c.426G>A p.W142* | Nonsense Mutation (SNP) | VAF 10/151 reads (7%) | catalogued as COSV100610238; called by muse, mutect2
- AKR1C2 | c.139C>T p.H47Y | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs782255440, COSV101060522; called by muse, mutect2, varscan2
- AKR1E2 | c.962G>C p.*321Sext*50 | Nonstop Mutation (SNP) | VAF 18/99 reads (18%) | catalogued as COSV100033672; called by muse, mutect2, varscan2
- AKT3 | c.453G>C p.L151F | Missense Mutation (SNP) | VAF 41/324 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99795304, COSV99796447; called by muse, mutect2, varscan2
- AL031777.2 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV61912045, COSV61912079; called by muse, mutect2, varscan2
- AL645922.1 | c.2902T>A p.Y968N | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.193); catalogued as COSV100191446; called by muse, varscan2
- ALOX15 | c.1196T>A p.I399N | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99541709; called by muse, mutect2, varscan2
- ALPK2 | c.4882G>C p.E1628Q | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV100864752, COSV64495174; called by muse, mutect2, varscan2
- ALX4 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100241236; called by muse, mutect2, varscan2
- AMMECR1L | c.846C>G p.I282M | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as COSV99761532; called by muse, mutect2, varscan2
- ANAPC1 | c.4945G>T p.E1649* | Nonsense Mutation (SNP) | VAF 75/496 reads (15%) | catalogued as COSV100595044; called by muse, mutect2, varscan2
- ANAPC4 | c.1393C>G p.R465G | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV100194212, COSV59544708; called by mutect2, varscan2
- ANGPTL5 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV57533814; called by muse, mutect2
- ANK2 | c.3094G>A p.E1032K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs775323997, COSV52150043; called by muse, mutect2, varscan2
- ANKRD12 | c.796-1G>C p.X266_splice | Splice Site (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100041984; called by muse, mutect2, varscan2
- AP2A2 | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100173291; called by muse, mutect2, varscan2
- APBA1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as COSV99596999; called by muse, mutect2, varscan2
- APC | c.4157G>A p.R1386K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99964360, COSV99969850; called by muse, mutect2, varscan2
- APC | c.7915G>C p.E2639Q | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.094); catalogued as rs878853472; ClinVar: uncertain significance; called by muse, mutect2
- APOBR | c.2452G>A p.E818K (on ENST00000431282; = p.E827K on NM_018690.4) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV100112330, COSV100112881; called by muse, mutect2, varscan2
- APOBR | c.2773G>A p.E925K (on ENST00000431282; = p.E934K on NM_018690.4) | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100112884; called by muse, mutect2, varscan2
- APOBR | c.3182G>C p.R1061T (on ENST00000431282; = p.R1070T on NM_018690.4) | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs781256543, COSV100112889; called by muse, mutect2, varscan2
- APOC2 | c.130C>G p.L44V | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.822); catalogued as COSV99377034; called by muse, mutect2, varscan2
- ARAF | c.1080G>C p.K360N | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99283433; called by muse, mutect2, varscan2
- ARHGAP31 | c.1258C>A p.L420I | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV99957651; called by muse, mutect2, varscan2
- ARHGAP35 | c.3966G>C p.K1322N | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101351586; called by muse, mutect2
- ARHGAP39 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.033); catalogued as COSV99432157; called by muse, mutect2, varscan2
- ARHGAP45 | c.2416G>T p.E806* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100491065; called by muse, mutect2, varscan2
- ARHGEF11 | c.2581G>A p.E861K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59357067; called by muse, mutect2, varscan2
- ARHGEF40 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100070661; called by muse, mutect2, varscan2
- ARHGEF6 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV99166674; called by muse, mutect2, varscan2
- ARHGEF7 | c.1483G>A p.E495K (on ENST00000375741 / NM_001113511.2; = p.E317K on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as rs765860102, COSV54540099; called by muse, mutect2, varscan2
- ARID1A | c.1177C>T p.Q393* | Nonsense Mutation (SNP) | VAF 26/127 reads (20%) | catalogued as COSV61376568; called by muse, mutect2, varscan2
- ARID1A | c.5834C>T p.P1945L | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV61389092; called by muse, mutect2, varscan2
- ARID4B | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV99936227; called by muse, varscan2
- ARL6IP6 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.127); catalogued as COSV100424117; called by muse, mutect2, varscan2
- ARRDC4 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.069); catalogued as COSV99164468; called by muse, mutect2
- ASIC3 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as rs766347273, COSV99874923; called by muse, mutect2, varscan2
- ASPM | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99660995; called by muse, mutect2, varscan2
- ASS1 | c.566+1G>A p.X189_splice | Splice Site (SNP) | VAF 14/65 reads (22%) | catalogued as COSV61690693; called by muse, mutect2, varscan2
- ASXL3 | c.5708C>T p.S1903L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as rs375291297; called by muse, mutect2, varscan2
- ATAD2B | c.3272C>G p.S1091* | Nonsense Mutation (SNP) | VAF 31/174 reads (18%) | catalogued as COSV99478367; called by muse, mutect2, varscan2
- ATF2 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99908965; called by muse, mutect2, varscan2
- ATG2A | c.2403C>G p.F801L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101034754; called by muse, mutect2, varscan2
- ATL1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as rs763902321, COSV100613288; called by muse, mutect2, varscan2
- ATN1 | c.3392C>G p.S1131C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57547335, COSV99980835; called by muse, mutect2
- ATP12A | c.963C>G p.F321L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV99518337; called by muse, mutect2, varscan2
- ATP13A3 | c.2949G>A p.M983I | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV99757580; called by muse, mutect2, varscan2
- ATP2B2 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV100660406; called by muse, mutect2
- ATP2B4 | c.2582G>C p.G861A | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1470618426, COSV100397995; called by muse, mutect2, varscan2
- ATP6V1C2 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV99696077; called by muse, varscan2
- ATRX | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 16/462 reads (3%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100969623, COSV64870096; called by muse, mutect2
- ATXN2 | c.2126C>T p.S709F (on ENST00000550104; = p.S549F on NM_002973.4) | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV101112899; called by muse, mutect2, varscan2
- AVPI1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.242); catalogued as rs150249445; called by muse, mutect2
- BAG6 | c.418C>T p.L140F | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99277545; called by muse, mutect2, varscan2
- BARHL2 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1422677109, COSV100966100; called by muse, mutect2, varscan2
- BEND3 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.042); catalogued as COSV100944666; called by muse, mutect2, varscan2
- BEND7 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 44/190 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100346999; called by muse, mutect2, varscan2
- BEST3 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV99876369; called by muse, mutect2, varscan2
- BIRC2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV99926888; called by muse, mutect2, varscan2
- BIRC3 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV99680188; called by muse, mutect2, varscan2
- BMX | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1467580394, COSV59593407; called by muse, mutect2, varscan2
- BRAF | c.335C>G p.S112C | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV99968304; called by muse, mutect2, varscan2
- BRAP | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 29/178 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100554254; called by muse, mutect2, varscan2
- BROX | c.108G>C p.L36F | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100572324; called by muse, mutect2, varscan2
- BTBD3 | c.1081C>T p.Q361* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99656121; called by muse, mutect2
- BTD | c.1506G>T p.R502S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100329811; called by muse, mutect2
- C11orf45 | c.49C>G p.P17A | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.015); catalogued as rs138330651, COSV100171591; called by muse, mutect2, varscan2
- C16orf70 | c.321G>C p.Q107H | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99531608; called by muse, mutect2, varscan2
- C16orf71 | c.1458G>C p.Q486H | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs767807614, COSV54789348, COSV99556451; called by muse, mutect2, varscan2
- C1orf127 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100983511, COSV100983529; called by muse, mutect2, varscan2
- C2CD5 | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as COSV100448986; called by muse, mutect2, varscan2
- C6orf120 | c.144G>C p.Q48H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.067); catalogued as COSV100179225; called by muse, mutect2, varscan2
- C7orf31 | c.1497C>G p.F499L | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV52216747, COSV99384131; called by muse, mutect2, varscan2
- C9orf131 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100398267; called by muse, mutect2, varscan2
- C9orf131 | c.641C>G p.S214* | Nonsense Mutation (SNP) | VAF 21/93 reads (23%) | catalogued as COSV100398269; called by muse, mutect2, varscan2
- C9orf131 | c.739C>G p.H247D | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.346); catalogued as COSV100398272; called by muse, mutect2, varscan2
- C9orf131 | c.2977C>T p.Q993* | Nonsense Mutation (SNP) | VAF 25/94 reads (27%) | catalogued as COSV100398275; called by muse, mutect2, varscan2
- CABIN1 | c.4066G>C p.D1356H | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99573903; called by muse, mutect2, varscan2
- CACNA1E | c.6047C>A p.S2016Y (on ENST00000367573 / NM_001205293.3; = p.S1973Y on NM_000721.4) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100704871; called by muse, mutect2, varscan2
- CACNB3 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV99975084; called by muse, mutect2, varscan2
- CADM4 | c.307T>G p.F103V | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.145); catalogued as COSV99731673; called by muse, mutect2, varscan2
- CADPS | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99340508; called by muse, mutect2, varscan2
- CADPS2 | c.582G>C p.L194F | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1188136337, COSV100465551; called by muse, mutect2, varscan2
- CALCR | c.1086G>C p.M362I (on ENST00000649521 / NM_001164737.2; = p.M346I on NM_001742.4) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100810828; called by muse, mutect2, varscan2
- CAMK2D | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99594584; called by muse, mutect2, varscan2
- CAMTA1 | c.4546C>G p.L1516V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1445927874, COSV57930648; called by muse, mutect2, varscan2
- CAPN11 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 8/124 reads (6%) | catalogued as COSV67237728; called by muse, mutect2
- CAPSL | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as COSV101274331, COSV68438029; called by muse, mutect2, varscan2
- CARD10 | c.1715C>G p.S572C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99324875, COSV99325330; called by muse, mutect2, varscan2
- CARHSP1 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs201523233, COSV100220146, COSV60683801; called by muse, mutect2, varscan2
- CASD1 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as COSV99802998; called by muse, mutect2, varscan2
- CASP8 | c.1116G>C p.E372D (on ENST00000432109 / NM_033355.3; = p.E389D on NM_001228.4) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99630785; called by muse, mutect2, varscan2
- CASP8AP2 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99387482; called by muse, mutect2, varscan2
- CASQ1 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV100927360; called by muse, mutect2
- CBY2 | c.1137G>C p.E379D | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV60118392; called by muse, mutect2
- CCAR2 | c.2452C>T p.R818C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); catalogued as COSV99374284; called by muse, mutect2, varscan2
- CCDC150 | c.3287C>T p.S1096F | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV99777331; called by muse, mutect2
- CCDC171 | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV99901790; called by muse, mutect2, varscan2
- CCDC39 | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99870464; called by muse, mutect2, varscan2
- CCDC57 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101052071; called by muse, mutect2, varscan2
- CCDC88A | c.3000G>T p.V1000= | Splice Region (SNP) | VAF 24/112 reads (21%) | catalogued as COSV99711092; called by muse, mutect2, varscan2
- CCER1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100727141; called by muse, mutect2, varscan2
- CCIN | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV100631941; called by muse, mutect2, varscan2
- CCNA1 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99714842; called by muse, mutect2, varscan2
- CCPG1 | c.1909C>T p.Q637* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | catalogued as COSV99380670; called by muse, mutect2, varscan2
- CD46 | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 24/261 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100523064; called by muse, mutect2
- CD84 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100246249; called by muse, mutect2, varscan2
- CD99L2 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100306567, COSV57986852; called by muse, mutect2
- CDH10 | c.2092C>T p.P698S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.285); catalogued as COSV52570072; called by muse, mutect2, varscan2
- CDH4 | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.844); catalogued as COSV100849491, COSV64642874; called by muse, mutect2, varscan2
- CDK18 | c.612G>C p.E204D (on ENST00000506784 / NM_212503.3; = p.E174D on NM_002596.4) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100774097; called by muse, mutect2, varscan2
- CECR2 | c.3943G>C p.E1315Q (on ENST00000342247 / NM_001290047.2; = p.E1131Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99378974; called by muse, mutect2
- CEMIP | c.2273C>G p.S758* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV55000991, COSV99587207; called by muse, mutect2, varscan2
- CENPE | c.1588G>C p.E530Q | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99478946; called by muse, mutect2, varscan2
- CENPF | c.2474C>T p.S825F | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.187); catalogued as COSV65280105; called by muse, mutect2, varscan2
- CENPF | c.6094C>G p.H2032D | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100871890, COSV100871928; called by muse, mutect2
- CEP120 | c.2467C>G p.L823V | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV100071428; called by muse, mutect2, varscan2
- CEP162 | c.3951G>C p.K1317N | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV100003320, COSV57618196; called by muse, mutect2, varscan2
- CHD2 | c.4091C>T p.S1364L | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV101245902; called by muse, mutect2, varscan2
- CHD4 | c.2197G>A p.D733N (on ENST00000357008 / NM_001363606.2; = p.D746N on NM_001273.5) | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); catalogued as COSV58901204; called by muse, varscan2
- CHD4 | c.2149C>G p.Q717E (on ENST00000357008 / NM_001363606.2; = p.Q730E on NM_001273.5) | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100539073; called by muse, varscan2
- CHD4 | c.1117G>A p.D373N (on ENST00000357008 / NM_001363606.2; = p.D386N on NM_001273.5) | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58901600, COSV58906983; called by muse, mutect2, varscan2
- CHD7 | c.181C>G p.Q61E | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.053); catalogued as COSV71108845; called by muse, mutect2, varscan2
- CHORDC1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100272155, COSV57706659; called by muse, mutect2, varscan2
- CHRNA4 | c.1277C>G p.S426C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV100937472; called by muse, mutect2, varscan2
- CHTF18 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs763378704, COSV99135967; called by muse, mutect2, varscan2
- CIZ1 | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV99477099; called by muse, mutect2, varscan2
- CIZ1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs770956884, COSV99477105; called by muse, mutect2
- CLASRP | c.1154C>T p.S385F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99674107; called by muse, mutect2, varscan2
- CLDND1 | c.403+1G>C p.X135_splice | Splice Site (SNP) | VAF 10/133 reads (8%) | catalogued as COSV100360802; called by muse, mutect2
- CLEC12A | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV100429664; called by muse, mutect2, varscan2
- CLHC1 | c.701G>A p.C234Y | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as COSV100811495; called by muse, mutect2, varscan2
- CLK4 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 69/325 reads (21%) | catalogued as COSV100309082; called by muse, mutect2, varscan2
- CLN3 | c.753G>T p.W251C (on ENST00000360019 / NM_001286104.2; = p.W275C on NM_000086.2) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.726); catalogued as COSV100343655; called by muse, mutect2, varscan2
- CLPB | c.1721C>G p.S574W | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99578606; called by muse, mutect2, varscan2
- CMYA5 | c.2288C>G p.S763C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV101484308; called by muse, mutect2, varscan2
- CMYA5 | c.10102G>A p.E3368K | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV71410270; called by muse, mutect2, varscan2
- CNOT11 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.148); catalogued as COSV99179368; called by muse, mutect2, varscan2
- CNOT6L | c.241C>G p.L81V (on ENST00000504123 / NM_001286790.2; = p.L76V on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53698742, COSV99362169; called by muse, mutect2, varscan2
- CNTN5 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 67/335 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs371947927; called by muse, mutect2, varscan2
- CNTNAP5 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as COSV101420662, COSV101420813; called by muse, mutect2, varscan2
- COBLL1 | c.3505G>A p.E1169K (on ENST00000392717; = p.E1131K on NM_014900.5) | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99528601; called by muse, mutect2, varscan2
- COL19A1 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 34/182 reads (19%) | catalogued as COSV100507303; called by muse, mutect2, varscan2
- COL4A3 | c.3466G>A p.D1156N | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100516844; called by muse, mutect2, varscan2
- COL6A3 | c.1195G>C p.V399L | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV99800901; called by muse, mutect2, varscan2
- COL7A1 | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs751405989, COSV100097522; called by muse, mutect2, varscan2
- COLEC10 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.412); catalogued as COSV60520773; called by muse, mutect2
- COP1 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100443839, COSV58174345; called by muse, mutect2
- COP1 | c.1011C>A p.F337L | Missense Mutation (SNP) | VAF 68/371 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.827); catalogued as COSV100443841; called by muse, mutect2, varscan2
- COPA | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as COSV99616660; called by muse, mutect2, varscan2
- CPA4 | c.714G>T p.W238C | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99745301; called by muse, mutect2, varscan2
- CPEB1 | c.788C>G p.S263* (on ENST00000617958; = p.S203* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/225 reads (15%) | catalogued as COSV99917971; called by muse, mutect2, varscan2
- CPLANE1 | c.8224G>C p.D2742H | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.105); catalogued as COSV57073365; called by muse, mutect2, varscan2
- CPS1 | c.3529G>C p.E1177Q | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99243939; called by muse, mutect2, varscan2
- CPT1B | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.802); catalogued as COSV100376818; called by muse, mutect2, varscan2
- CR2 | c.2906G>C p.R969T | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV100889699, COSV65507148; called by muse, mutect2, varscan2
- CREBBP | c.2368C>A p.Q790K | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99271651; called by muse, mutect2, varscan2
- CREBRF | c.1459G>C p.D487H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99756320; called by muse, mutect2, varscan2
- CRISPLD1 | c.79C>G p.P27A | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV100082391, COSV51553129; called by muse, mutect2, varscan2
- CRTAC1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100086064; called by muse, mutect2, varscan2
- CRYBG1 | c.5465G>A p.R1822Q | Missense Mutation (SNP) | VAF 47/358 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs767966320, COSV64810992; called by muse, mutect2, varscan2
- CSPP1 | c.3074G>A p.R1025K (on ENST00000676605; = p.R984K on NM_024790.6) | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as rs753413923, COSV99139708; called by muse, mutect2, varscan2
- CTDSPL | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99828990; called by muse, mutect2, varscan2
- CTNNA3 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 40/170 reads (24%) | catalogued as COSV101051420; called by muse, mutect2, varscan2
- CTNND2 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100480538; called by muse, mutect2, varscan2
- CTSB | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV100565943; called by muse, mutect2, varscan2
- CUBN | c.3352C>T p.P1118S | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV100913423; called by muse, mutect2, varscan2
- CUL3 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.816); catalogued as COSV100024659, COSV52368257; called by muse, mutect2, varscan2
- CUL4A | c.2189G>A p.G730E (on ENST00000375440 / NM_001008895.4; = p.G630E on NM_003589.3) | Missense Mutation (SNP) | VAF 43/291 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100417502; called by muse, mutect2, varscan2
- CXorf21 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV100973355; called by muse, mutect2, varscan2
- CYFIP1 | c.3367G>A p.E1123K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.442); catalogued as rs748203521, COSV100488716; called by muse, mutect2, varscan2
- CYP4F11 | c.372C>G p.F124L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as COSV56128139, COSV99931089; called by muse, mutect2, varscan2
- DAB1 | c.1468G>A p.D490N (on ENST00000371231; = p.D457N on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.735); catalogued as rs867320302, COSV64695274; called by muse, mutect2, varscan2
- DCC | c.1339C>T p.L447F | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs149507808; called by muse, varscan2
- DCHS1 | c.3082G>A p.D1028N | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV55046096; called by muse, mutect2, varscan2
- DCHS1 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100202514, COSV100202560; called by muse, mutect2, varscan2
- DCLRE1B | c.1477C>G p.L493V | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV100849843; called by muse, mutect2, varscan2
- DCP1B | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99767893; called by muse, mutect2, varscan2
- DCTN1 | c.2262G>C p.Q754H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as COSV100721056; called by muse, mutect2, varscan2
- DCTN1 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.988); catalogued as rs761071126, COSV100721057; called by muse, mutect2, varscan2
- DCTN1 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1190720475, COSV100721059; called by muse, mutect2, varscan2
- DCTN5 | c.440C>G p.S147* | Nonsense Mutation (SNP) | VAF 9/114 reads (8%) | catalogued as COSV100266063; called by muse, mutect2
- DDX43 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562284533, COSV100946486; called by muse, mutect2, varscan2
- DEAF1 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58609565; called by muse, mutect2, varscan2
- DENND4C | c.5605C>T p.Q1869* (on ENST00000434457 / NM_001330640.2; = p.Q1820* on NM_017925.7) | Nonsense Mutation (SNP) | VAF 35/182 reads (19%) | catalogued as COSV100727582; called by muse, mutect2, varscan2
- DGKI | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | catalogued as COSV99936974; called by muse, mutect2
- DICER1 | c.4430C>G p.S1477C | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV100602492; called by muse, mutect2, varscan2
- DLL3 | c.1714C>A p.Q572K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99219424; called by muse, varscan2
- DMAP1 | c.1345-1G>C p.X449_splice | Splice Site (SNP) | VAF 13/69 reads (19%) | catalogued as COSV100261833; called by muse, mutect2, varscan2
- DMRTA2 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.985); catalogued as COSV68672499; called by muse, mutect2
- DNAH10 | c.13012C>G p.L4338V (on ENST00000409039; = p.L4277V on NM_207437.3) | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV99435869; called by muse, mutect2, varscan2
- DNAH2 | c.11702C>T p.S3901F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101209562; called by muse, mutect2, varscan2
- DNAH3 | c.7890G>C p.E2630D | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.944); catalogued as COSV99770202; called by muse, mutect2, varscan2
- DNAJA4 | c.869C>T p.S290F (on ENST00000343789; = p.S319F on NM_018602.3) | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as rs1235451823, COSV100655240; called by muse, mutect2, varscan2
- DNAJC6 | c.2309C>G p.S770* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV99675542; called by muse, mutect2, varscan2
- DOCK2 | c.4158G>C p.E1386D | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV99914915; called by muse, mutect2, varscan2
- DSCAML1 | c.3976G>A p.A1326T (on ENST00000321322; = p.A1266T on NM_020693.4) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.898); catalogued as COSV100357008; called by muse, mutect2, varscan2
- DSG4 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100356360; called by muse, mutect2
- DUOX1 | c.3949G>A p.E1317K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376478271; called by muse, mutect2, varscan2
- DYDC1 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99758180; called by muse, mutect2, varscan2
- DYNC1I1 | c.1025C>G p.S342C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV100269142, COSV61463927; called by muse, mutect2, varscan2
- DYNC1LI1 | c.30C>A p.F10L | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.827); catalogued as COSV56126711, COSV99818319; called by muse, mutect2, varscan2
- DYNC2H1 | c.12505G>C p.D4169H | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs886505169, COSV100519578; called by muse, mutect2, varscan2
- EED | c.359G>C p.R120T | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV99646586; called by muse, mutect2, varscan2
- EFCAB5 | c.2635C>T p.Q879* | Nonsense Mutation (SNP) | VAF 16/111 reads (14%) | catalogued as COSV100300639; called by muse, mutect2, varscan2
- EGFL6 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as COSV100789896, COSV100789950; called by muse, mutect2
- EGLN1 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1293106237, CM163981, COSV64150691; called by muse, mutect2, varscan2
- EHBP1 | c.289G>C p.E97Q | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99861728; called by muse, mutect2, varscan2
- EIF3I | c.99C>T p.I33= | Splice Region (SNP) | VAF 23/125 reads (18%) | catalogued as rs957880767, COSV59084272; called by muse, mutect2, varscan2
- EIF4A1 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as COSV51511160, COSV99549219; called by muse, mutect2, varscan2
- EIF4A2 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV60623812, COSV60624846; called by muse, mutect2
- ELOA2 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV99797788; called by muse, mutect2, varscan2
- EPC1 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 23/145 reads (16%) | catalogued as COSV99553389; called by muse, mutect2, varscan2
- EPC2 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 51/257 reads (20%) | catalogued as COSV99310128; called by muse, mutect2, varscan2
- EPHA4 | c.2934G>C p.Q978H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99917359; called by muse, mutect2, varscan2
- EPHA8 | c.1862G>T p.R621L | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV51263394, COSV51265872; called by muse, mutect2, varscan2
- ERCC3 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1163407906, COSV99573642; called by muse, mutect2
- ERCC4 | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 34/194 reads (18%) | catalogued as COSV100319068, COSV61311015; called by muse, mutect2, varscan2
- ERCC4 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.152); catalogued as COSV100319069, COSV61311360, COSV61312377; called by muse, mutect2, varscan2
- ESR1 | c.51G>C p.Q17H | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99240882; called by muse, mutect2, varscan2
- ESRP1 | c.1479C>G p.I493M | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100619578; called by muse, mutect2, varscan2
- ETFDH | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV100306971; called by muse, mutect2, varscan2
- EVI2B | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100445634; called by muse, mutect2, varscan2
- EXOC3 | c.1861G>C p.E621Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV100155542; called by muse, mutect2
- EXOG | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV55063904; called by muse, mutect2, varscan2
- F8 | c.5131C>T p.Q1711* | Nonsense Mutation (SNP) | VAF 34/127 reads (27%) | catalogued as CM1314194, COSV100811840, COSV64275769; called by muse, mutect2, varscan2
- FA2H | c.709C>A p.L237M | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99547888; called by muse, mutect2, varscan2
- FAM47A | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.22); catalogued as COSV100650047; called by muse, mutect2, varscan2
- FAM98B | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV99989133; called by muse, mutect2, varscan2
- FAT2 | c.12226C>T p.H4076Y | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV99943952; called by muse, mutect2, varscan2
- FBXL13 | c.2158G>C p.E720Q | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.298); catalogued as COSV100502045; called by muse, mutect2
- FBXL22 | c.87G>T p.R29S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100634438; called by muse, varscan2
- FBXL22 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.284); catalogued as COSV100634440; called by muse, varscan2
- FBXO11 | c.1892G>C p.R631T (on ENST00000403359 / NM_001190274.2; = p.R547T on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV100319910; called by muse, mutect2, varscan2
- FBXO38 | c.3271G>A p.E1091K (on ENST00000340253 / NM_205836.3; = p.E1016K on NM_030793.5) | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99693887; called by muse, mutect2, varscan2
- FCHO2 | c.662C>G p.S221* | Nonsense Mutation (SNP) | VAF 30/160 reads (19%) | catalogued as COSV99822054; called by muse, mutect2, varscan2
- FCHSD1 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 18/94 reads (19%) | catalogued as COSV101447611; called by muse, mutect2, varscan2
- FCRL4 | c.1504G>C p.D502H | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV54864974, COSV99620364; called by muse, mutect2, varscan2
- FLAD1 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV52698998, COSV99422955; called by muse, mutect2, varscan2
- FLG | c.11335G>C p.D3779H | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100912053; called by muse, mutect2, varscan2
- FLNB | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV55869084, COSV99914537; called by muse, mutect2, varscan2
- FMN2 | c.4435G>C p.E1479Q | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.632); catalogued as COSV100146952, COSV60458558; called by muse, mutect2
- FMO5 | c.560G>C p.R187T | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs781850993, COSV99567407; called by muse, mutect2, varscan2
- FMO5 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as rs781795531, COSV99567410; called by muse, mutect2, varscan2
- FMR1 | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV54423836, COSV99503744; called by muse, mutect2
- FNDC1 | c.1367C>T p.T456I | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV99796586; called by muse, mutect2, varscan2
- FNDC3A | c.1842G>A p.M614I (on ENST00000492622 / NM_001079673.2; = p.M558I on NM_014923.5) | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV101256929; called by muse, mutect2, varscan2
- FOSL1 | c.8G>C p.R3P | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100440971; called by muse, mutect2
- FOXA1 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51650573, COSV99163750; called by muse, mutect2, varscan2
- FOXA1 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99163751; called by muse, mutect2, varscan2
- FOXO4 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV100447045; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.826); catalogued as COSV100437771, COSV58552084; called by muse, mutect2, varscan2
- FRMD4B | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.318); catalogued as COSV101273661; called by muse, mutect2, varscan2
- FRMD5 | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as COSV101296690; called by muse, mutect2, varscan2
- FRMPD3 | c.3155C>G p.S1052* | Nonsense Mutation (SNP) | VAF 28/133 reads (21%) | catalogued as COSV99346971; called by muse, mutect2, varscan2
- FSCN2 | c.236G>C p.C79S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100603335; called by muse, mutect2, varscan2
- FUBP1 | c.997C>G p.Q333E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.055); catalogued as COSV53933945; called by muse, mutect2, varscan2
- FUCA1 | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100992199; called by muse, mutect2, varscan2
- FZD5 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as rs772754333, COSV99776497; called by muse, mutect2, varscan2
- GAB1 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs761657658, COSV99528768; called by muse, mutect2, varscan2
- GABBR2 | c.1636G>T p.E546* | Nonsense Mutation (SNP) | VAF 21/106 reads (20%) | catalogued as COSV99411287; called by muse, mutect2, varscan2
- GABPB1 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 17/112 reads (15%) | catalogued as COSV99590053; called by muse, mutect2, varscan2
- GABRA6 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV50880855, COSV99194053; called by muse, mutect2, varscan2
- GALNT10 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs751497664, COSV51725140; called by muse, mutect2, varscan2
- GALNT11 | c.1739G>A p.R580K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100232019; called by muse, mutect2, varscan2
- GALNT14 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs142569800, COSV61104229; called by muse, mutect2
- GALNTL5 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 9/250 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1217719851; called by muse, mutect2
- GALR1 | c.977C>G p.S326* | Nonsense Mutation (SNP) | VAF 16/100 reads (16%) | catalogued as COSV100231955, COSV100232078, COSV55316248; called by muse, mutect2, varscan2
- GAREM1 | c.561C>G p.I187M | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV99331294; called by muse, mutect2, varscan2
- GAS2L2 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs782075862; called by muse, mutect2, varscan2
- GAS7 | c.945G>A p.M315I (on ENST00000432992 / NM_201433.2; = p.M175I on NM_003644.3) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV100096800; called by muse, mutect2, varscan2
- GBP3 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 39/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99352513, COSV99352718; called by muse, mutect2, varscan2
- GFM2 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.102); catalogued as COSV99714657; called by muse, mutect2
- GIMAP2 | c.704G>C p.R235T | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV99785226; called by muse, mutect2, varscan2
- GNL1 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs974956352, COSV100925446; called by muse, mutect2, varscan2
- GOLGB1 | c.4351G>A p.D1451N | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs761066625, COSV61467593; called by muse, mutect2, varscan2
- GON4L | c.1822G>C p.D608H | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99675590; called by muse, mutect2
- GORAB | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 27/224 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100883784; called by muse, mutect2, varscan2
- GPC5 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV100995667; called by muse, mutect2, varscan2
- GPR108 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as COSV51187492, COSV99901522; called by muse, mutect2, varscan2
- GPR158 | c.3062C>T p.S1021L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV100894217, COSV66270112; called by muse, mutect2, varscan2
- GPS2 | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV59748707; called by muse, mutect2, varscan2
- GPX8 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV99697333; called by muse, mutect2
- GRIK3 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0.018); catalogued as COSV100902267; called by muse, mutect2
- GRIP1 | c.2184G>C p.L728F (on ENST00000359742 / NM_001379345.1; = p.L676F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99670789; called by muse, mutect2, varscan2
- GRM1 | c.3382G>A p.E1128K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.015); catalogued as rs1293559679, COSV99265028; called by muse, mutect2, varscan2
- GRM2 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as COSV99623118; called by muse, mutect2, varscan2
- GRM3 | c.630G>C p.W210C | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64473869; called by muse, mutect2, varscan2
- GTF2H3 | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99967655; called by muse, mutect2, varscan2
- GTF3C1 | c.3554C>T p.S1185F | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs973079409, COSV100649665; called by muse, mutect2, varscan2
- GTF3C3 | c.128C>G p.S43* | Nonsense Mutation (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99826965; called by muse, mutect2, varscan2
- GYS2 | c.1289G>C p.R430T | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99680175; called by muse, mutect2, varscan2
- GZMH | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99362041; called by muse, mutect2, varscan2
- H1-2 | c.551A>G p.K184R | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100642326; called by muse, mutect2
- H3C13 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 27/281 reads (10%) | catalogued as COSV100516165, COSV58943895, COSV58944644; called by muse, mutect2
- H3C2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV52517721, COSV52518221; called by muse, mutect2, varscan2
- H4C13 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as rs200412707, COSV100138057; called by muse, varscan2
- HAS2 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100392137; called by muse, mutect2
- HAUS4 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV99247112; called by muse, mutect2
- HAX1 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99672180; called by muse, mutect2, varscan2
- HBP1 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.95); catalogued as rs1180463300, COSV99753536; called by muse, mutect2, varscan2
- HCFC1 | c.2029-1G>C p.X677_splice | Splice Site (SNP) | VAF 13/70 reads (19%) | catalogued as COSV100129774; called by muse, mutect2, varscan2
- HCFC1R1 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.342); catalogued as COSV99560795; called by muse, mutect2, varscan2
- HCLS1 | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV100101070; called by muse, mutect2, varscan2
- HDAC4 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV100614145; called by muse, mutect2, varscan2
- HDX | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.396); catalogued as COSV99947963; called by muse, mutect2, varscan2
- HEATR5B | c.814G>C p.E272Q | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.305); catalogued as COSV99250114; called by muse, mutect2, varscan2
- HERC1 | c.620C>G p.S207* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV101496852; called by muse, mutect2, varscan2
- HERC2 | c.7674G>C p.L2558F | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.761); catalogued as COSV55345033, COSV99876439; called by muse, mutect2, varscan2
- HHLA2 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV100755525; called by muse, varscan2
- HIF3A | c.49G>A p.E17K (on ENST00000377670 / NM_152795.4; = p.E15K on NM_152794.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99356032; called by muse, mutect2, varscan2
- HIVEP1 | c.3596C>G p.S1199* | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as COSV101045660; called by muse, mutect2, varscan2
- HMCN1 | c.7393G>A p.E2465K | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1378252669, COSV99634806; called by muse, mutect2, varscan2
- HMG20B | c.627G>T p.M209I | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as COSV99503168; called by muse, mutect2, varscan2
- HMOX1 | c.141C>G p.F47L | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs367932474; called by mutect2, varscan2
- HOXB9 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60817944; called by muse, mutect2, varscan2
- HPS3 | c.1411G>C p.D471H | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.51); catalogued as COSV99937589; called by muse, mutect2, varscan2
- HPS4 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as COSV100404660; called by muse, varscan2
- HSF2 | c.87G>A p.W29* | Nonsense Mutation (SNP) | VAF 13/97 reads (13%) | catalogued as COSV100869716; called by muse, mutect2, varscan2
- HTT | c.6190C>G p.L2064V | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as COSV100751172; called by muse, mutect2, varscan2
- ICE1 | c.3328G>C p.E1110Q | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV99665559; called by muse, mutect2
- IDE | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV99794363; called by muse, mutect2, varscan2
- IDH1 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.083); catalogued as COSV61646717; called by muse, varscan2
- IDH1 | c.749T>G p.L250R | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100577298; called by muse, varscan2
- IFIH1 | c.630G>C p.E210D | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV55124454; called by muse, mutect2, varscan2
- IFIT3 | c.383C>G p.S128* | Nonsense Mutation (SNP) | VAF 16/109 reads (15%) | catalogued as COSV99260885; called by muse, mutect2, varscan2
- IFNAR2 | c.756G>C p.L252F | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100577164; called by muse, mutect2, varscan2
- IGSF9B | c.2479A>T p.I827F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV100318316; called by muse, mutect2, varscan2
- IKZF3 | c.320C>G p.S107* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99500123; called by muse, mutect2, varscan2
- ILDR2 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as rs781739777, COSV54830974; called by muse, mutect2, varscan2
- IMMT | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99607572; called by muse, mutect2, varscan2
- INCENP | c.2540G>A p.R847Q (on ENST00000394818 / NM_001040694.2; = p.R843Q on NM_020238.3) | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.895); catalogued as rs780988487, COSV99611425; called by muse, mutect2, varscan2
- INKA1 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100323741; called by muse, mutect2, varscan2
- INO80D | c.2728G>A p.D910N | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV101305878; called by muse, mutect2
- INTS7 | c.2626G>C p.E876Q | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV100877556; called by muse, mutect2, varscan2
- IPO8 | c.2422C>T p.H808Y | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.424); catalogued as COSV56241039, COSV56242004, COSV56242337; called by muse, mutect2, varscan2
- IQGAP3 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.601); catalogued as rs1221749675, COSV100752333; called by muse, mutect2, varscan2
- IQSEC1 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs926747306, COSV99832287; called by muse, mutect2, varscan2
- ITGA10 | c.2572C>T p.Q858* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100995030; called by muse, mutect2, varscan2
- ITGA8 | c.2923G>C p.E975Q | Missense Mutation (SNP) | VAF 49/231 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs762605347, COSV100959636; called by muse, mutect2, varscan2
- ITIH4 | c.417G>C p.K139N | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); catalogued as COSV99819812; called by muse, varscan2
- ITPR2 | c.771G>C p.E257D | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as COSV101190134; called by muse, mutect2
- ITPR3 | c.6541G>A p.E2181K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100967190, COSV100968039; called by muse, mutect2, varscan2
- IWS1 | c.986C>G p.S329* | Nonsense Mutation (SNP) | VAF 21/110 reads (19%) | catalogued as COSV99767499; called by muse, mutect2, varscan2
- JAK2 | c.398G>C p.R133P | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101078850; called by muse, mutect2, varscan2
- JAKMIP3 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV100059828; called by muse, mutect2, varscan2
- JCAD | c.2294C>T p.S765L | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as COSV64758177; called by muse, mutect2, varscan2
- KALRN | c.4363G>A p.D1455N | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53765161; called by muse, mutect2, varscan2
- KANSL2 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.208); catalogued as COSV100771047; called by muse, mutect2, varscan2
- KAT2B | c.2221-1G>C p.X741_splice | Splice Site (SNP) | VAF 22/99 reads (22%) | catalogued as COSV99769843; called by muse, mutect2, varscan2
- KAT6B | c.3693G>C p.L1231F | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as COSV99768931; called by muse, mutect2, varscan2
- KATNA1 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.864); catalogued as COSV100167974; called by muse, mutect2, varscan2
- KCNA10 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100871484; called by muse, mutect2, varscan2
- KCNG1 | c.1529G>A p.R510K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as rs763411967, COSV100857165; called by muse, mutect2, varscan2
- KCNH5 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100527908; called by muse, mutect2, varscan2
- KCNJ16 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV99033402, COSV99388670; called by muse, mutect2, varscan2
- KCNJ9 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.086); catalogued as COSV58757865; called by muse, mutect2, varscan2
- KCNK1 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100785767; called by muse, mutect2, varscan2
- KCNQ5 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 23/173 reads (13%) | catalogued as COSV100572949, COSV59656592; called by muse, mutect2, varscan2
- KIAA0100 | c.5221G>C p.D1741H | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101197398; called by muse, mutect2, varscan2
- KIAA0319 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.057); catalogued as COSV100985774; called by muse, mutect2, varscan2
- KIAA1109 | c.5587G>A p.E1863K | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99173862; called by muse, mutect2, varscan2
- KIAA1328 | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV99695227; called by muse, mutect2, varscan2
- KIF13A | c.4210G>C p.D1404H | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.45); catalogued as COSV99437871; called by muse, mutect2, varscan2
- KIF13A | c.2327G>A p.R776Q | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.385); catalogued as rs1232479730, COSV99437877; called by muse, mutect2
- KIF1C | c.2314G>C p.E772Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as rs780072767, COSV100296987, COSV100297288; called by muse, mutect2, varscan2
- KIF21A | c.3986C>G p.S1329* (on ENST00000361418 / NM_001378440.1; = p.S1316* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/104 reads (16%) | catalogued as COSV100735614; called by muse, mutect2, varscan2
- KIF21A | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV100735615; called by muse, varscan2
- KIF5C | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.214); catalogued as COSV101469558; called by muse, mutect2, varscan2
- KLHL15 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 36/197 reads (18%) | catalogued as COSV100044410; called by muse, mutect2, varscan2
- KLHL31 | c.1373G>A p.C458Y | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100911847; called by muse, mutect2
- KMT2D | c.10413G>C p.Q3471H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV99985377; called by muse, mutect2, varscan2
- KMT2E | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99996904; called by muse, mutect2, varscan2
- KNG1 | c.1822G>A p.D608N | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV99405820; called by muse, mutect2, varscan2
- KRI1 | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 25/204 reads (12%) | catalogued as COSV100224881; called by muse, varscan2
- KRT19 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54179901, COSV99563256; called by muse, varscan2
- KRT33A | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.57); catalogued as rs779297022, COSV50365847; called by muse, mutect2, varscan2
- KRT6B | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV99360961; called by muse, mutect2
- KRT6C | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99360175; called by muse, mutect2, varscan2
- KRTAP1-1 | c.275G>C p.G92A | Missense Mutation (SNP) | VAF 49/194 reads (25%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.511); catalogued as COSV100092257; called by muse, mutect2, varscan2
- KRTAP10-4 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.509); catalogued as rs201736033; called by muse, mutect2, varscan2
- L3MBTL4 | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.036); catalogued as COSV99526784, COSV99530828; called by muse, mutect2, varscan2
- LAMA1 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.516); catalogued as COSV101057535; called by muse, mutect2, varscan2
- LAMB3 | c.2399C>T p.S800L | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV100620503; called by muse, mutect2, varscan2
- LAMC2 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs564730705, COSV99917872; called by muse, mutect2
- LARP1 | c.1567C>T p.R523C (on ENST00000518297 / NM_033551.3; = p.R446C on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs946835367, COSV100304041; called by muse, mutect2, varscan2
- LATS2 | c.2785G>C p.E929Q | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.374); catalogued as COSV101231661; called by muse, mutect2, varscan2
- LBX1 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV100929969; called by muse, mutect2, varscan2
- LCK | c.876G>C p.M292I | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV60740078, COSV60742627; called by muse, mutect2, varscan2
- LCT | c.4135G>C p.E1379Q | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.083); catalogued as COSV99930308; called by muse, mutect2, varscan2
- LCTL | c.1201C>T p.Q401* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as rs1452242690, COSV100328923; called by muse, mutect2, varscan2
- LGALSL | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV99482544; called by muse, mutect2, varscan2
- LGR6 | c.1312C>T p.P438S (on ENST00000367278 / NM_001017403.1; = p.P386S on NM_021636.3) | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs921594707, COSV99707757; called by muse, mutect2, varscan2
- LMNTD1 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99280251; called by muse, varscan2
- LMTK3 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99541107; called by muse, mutect2, varscan2
- LONP2 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53526662, COSV99589473; called by muse, mutect2, varscan2
- LPGAT1 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV65351516; called by muse, mutect2, varscan2
- LRCH1 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV100244033, COSV60846241; called by muse, mutect2, varscan2
- LRIG3 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754028410, COSV100292806; called by muse, mutect2, varscan2
- LRP1B | c.12301G>A p.D4101N | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs267598906, COSV101260121; called by muse, mutect2, varscan2
- LRP1B | c.3106G>C p.D1036H | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101260122, COSV67284771; called by muse, mutect2, varscan2
- LRP2 | c.12085G>C p.E4029Q | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as COSV99790004; called by muse, mutect2, varscan2
- LRP8 | c.2328G>T p.E776D | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.225); catalogued as COSV100035991; called by muse, mutect2, varscan2
- LRRC32 | c.610C>G p.L204V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99477254; called by muse, mutect2, varscan2
- LRRC7 | c.1485G>A p.M495I (on ENST00000651989 / NM_001370785.2; = p.M462I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV99229392; called by muse, mutect2
- LRRC7 | c.2116G>A p.D706N (on ENST00000651989 / NM_001370785.2; = p.D673N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50430434, COSV50450102; called by muse, mutect2, varscan2
- LRRC8C | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 15/89 reads (17%) | catalogued as COSV100968400; called by muse, mutect2, varscan2
- LRRK1 | c.2907G>C p.E969D | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as COSV99442758; called by muse, mutect2, varscan2
- LSG1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs547942305, COSV54570282; called by muse, mutect2, varscan2
- LTK | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.781); catalogued as COSV53029960; called by muse, mutect2, varscan2
- LUC7L2 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100722245; called by muse, mutect2, varscan2
- LURAP1L | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100070888; called by muse, mutect2
- LYST | c.825G>C p.L275F | Missense Mutation (SNP) | VAF 51/324 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV101090165; called by muse, mutect2, varscan2
- MAB21L1 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs764024059, COSV59771328; called by muse, mutect2, varscan2
- MACF1 | c.13999C>G p.Q4667E (on ENST00000372915; = p.Q2600E on NM_012090.5) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as COSV99246470; called by muse, mutect2, varscan2
- MAGEA10 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV99726891; called by muse, mutect2, varscan2
- MAGI3 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.088); catalogued as rs1380597944, COSV100290252; called by muse, mutect2, varscan2
- MAGI3 | c.2056C>A p.Q686K | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV100290255; called by muse, mutect2, varscan2
- MAN2A1 | c.1679G>A p.R560K | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1285270695, COSV99811805; called by muse, mutect2, varscan2
- MAN2A1 | c.2344G>C p.E782Q | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV99811808; called by muse, mutect2, varscan2
- MAN2B1 | c.3008C>A p.S1003* | Nonsense Mutation (SNP) | VAF 33/149 reads (22%) | catalogued as COSV99667272; called by muse, mutect2, varscan2
- MAOB | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.105); catalogued as COSV100956223; called by muse, mutect2, varscan2
- MAP1A | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449810482, COSV55807140; called by muse, mutect2, varscan2
- MAP1B | c.6446C>A p.S2149* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV57095710, COSV99702885; called by muse, mutect2
- MAP3K1 | c.1592C>A p.S531* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV101267096; called by muse, mutect2, varscan2
- MAP3K13 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99407817; called by muse, mutect2, varscan2
- MAP3K19 | c.1838C>G p.S613* | Nonsense Mutation (SNP) | VAF 16/100 reads (16%) | catalogued as COSV100209148; called by muse, mutect2, varscan2
- MAPK15 | c.351C>G p.I117M | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100568066; called by muse, mutect2
- MAPKAPK5 | c.338G>T p.R113I | Missense Mutation (SNP) | VAF 29/220 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101612905; called by muse, mutect2, varscan2
- MAPRE3 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV99252000; called by muse, mutect2, varscan2
- MARK4 | c.465G>C p.E155D | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99488748; called by muse, mutect2, varscan2
- MCC | c.2340G>C p.K780N | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56728001; called by muse, mutect2, varscan2
- MCM6 | c.1756-1G>A p.X586_splice | Splice Site (SNP) | VAF 7/40 reads (18%) | catalogued as COSV99919350; called by muse, mutect2
- MDH1B | c.1376G>C p.G459A | Missense Mutation (SNP) | VAF 41/212 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100982292; called by muse, mutect2, varscan2
- MDM2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as COSV99254866; called by muse, mutect2, varscan2
- MDN1 | c.14416G>C p.D4806H | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV101021771; called by muse, mutect2, varscan2
- MECOM | c.859C>T p.H287Y (on ENST00000468789 / NM_001105078.4; = p.H475Y on NM_004991.4) | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as COSV99245252; called by muse, mutect2, varscan2
- MEGF10 | c.2312C>T p.S771F | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99175511; called by muse, mutect2, varscan2
- MGAT2 | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.065); catalogued as COSV100023626; called by muse, mutect2, varscan2
- MGAT3 | c.89C>G p.S30C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.862); catalogued as COSV100362054; called by muse, mutect2, varscan2
- MICOS13 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100028692; called by muse, mutect2
- MID1 | c.1436T>A p.L479* | Nonsense Mutation (SNP) | VAF 13/95 reads (14%) | catalogued as COSV100452687; called by muse, mutect2, varscan2
- MIF4GD | c.134C>G p.S45C (on ENST00000325102 / NM_001370592.1; = p.S79C on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99821707; called by muse, mutect2, varscan2
- MIGA2 | c.479G>T p.R160I | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV99477837; called by muse, mutect2, varscan2
- MIGA2 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.099); catalogued as COSV99477842; called by muse, mutect2, varscan2
- MILR1 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV101660244; called by muse, mutect2, varscan2
- MLF1 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs763171016, COSV100576048; called by muse, mutect2, varscan2
- MME | c.1468G>C p.D490H | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV100852257, COSV100852515; called by muse, mutect2, varscan2
- MOAP1 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99365781; called by muse, mutect2, varscan2
- MPDZ | c.4846G>C p.D1616H | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100057417; called by muse, mutect2, varscan2
- MROH1 | c.4397G>A p.R1466Q | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs934630310; called by muse, mutect2, varscan2
- MRPL35 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 29/128 reads (23%) | catalogued as rs1157764222, COSV99383289; called by muse, mutect2, varscan2
- MRS2 | c.1043C>G p.S348C | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.925); catalogued as COSV99219110; called by muse, mutect2, varscan2
- MS4A15 | c.306C>G p.I102M (on ENST00000405633 / NM_001098835.2; = p.I9M on NM_152717.3) | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV100558954; called by muse, mutect2, varscan2
- MSLN | c.1352C>T p.S451F (on ENST00000382862 / NM_013404.4; = p.S443F on NM_005823.6) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.009); catalogued as rs201807512, COSV53505240, COSV99558676; called by muse, mutect2, varscan2
- MTA3 | c.452G>C p.R151T | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101290745; called by muse, mutect2, varscan2
- MTA3 | c.1248G>C p.L416F | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100780941; called by muse, mutect2, varscan2
- MTMR8 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66392602; called by muse, mutect2, varscan2
- MUC16 | c.23866G>A p.D7956N | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs372572295; called by muse, mutect2, varscan2
- MUC16 | c.13849G>A p.E4617K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.583); catalogued as COSV101198175, COSV67465081; called by muse, mutect2
- MVB12B | c.626C>A p.S209* | Nonsense Mutation (SNP) | VAF 27/127 reads (21%) | catalogued as COSV100753118; called by muse, mutect2, varscan2
- MXRA5 | c.5831C>T p.S1944L | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as rs137882293, COSV54230970; called by muse, mutect2, varscan2
- MYCN | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV99808525; called by muse, mutect2, varscan2
- MYH1 | c.1602C>G p.F534L | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as COSV56853339, COSV99876732; called by muse, mutect2, varscan2
- MYH9 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV53391823; called by muse, mutect2, varscan2
- MYLK | c.363G>C p.L121F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100659539, COSV60606929; called by muse, mutect2, varscan2
- MYNN | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.179); catalogued as COSV100377569; called by muse, mutect2
- MYO10 | c.4297G>C p.E1433Q | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99946147; called by muse, mutect2, varscan2
- MYO15A | c.4837C>T p.Q1613* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as COSV52752772; called by muse, mutect2
- MYO18B | c.5143G>C p.E1715Q | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); catalogued as COSV100124962; called by muse, mutect2, varscan2
- MYO3B | c.1003C>T p.H335Y | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100511527; called by muse, mutect2, varscan2
- MYOM1 | c.3042G>C p.M1014I | Missense Mutation (SNP) | VAF 4/85 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1350893428, COSV55291629, COSV55297314; called by muse, mutect2
- N4BP3 | c.496C>G p.Q166E | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772816113, COSV51063711; called by muse, mutect2, varscan2
- NAGA | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as CM078422, COSV101124174, COSV101124176; called by muse, mutect2, varscan2
- NAV1 | c.2251G>A p.D751N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as COSV99819569; called by muse, mutect2, varscan2
- NCAM1 | c.942G>C p.E314D | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.472); catalogued as COSV100378448; called by muse, mutect2, varscan2
- NCKAP1 | c.2712G>C p.L904F | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV62941813; called by muse, mutect2
- NCOR2 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1332749450, COSV62293255; called by muse, mutect2, varscan2
- NDP | c.86C>G p.S29* | Nonsense Mutation (SNP) | VAF 17/110 reads (15%) | catalogued as CM920496, COSV65203890; called by muse, mutect2, varscan2
- NEB | c.18978G>C p.Q6326H | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as COSV99427230; called by muse, mutect2, varscan2
- NEIL3 | c.1610G>A p.R537K | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as COSV99220896; called by muse, mutect2
- NEK4 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99238078; called by muse, mutect2, varscan2
- NEK5 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs372582723; called by muse, mutect2, varscan2
- NELL1 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.308); catalogued as COSV100124485, COSV54236095; called by muse, mutect2, varscan2
- NELL1 | c.2383-1G>A p.X795_splice | Splice Site (SNP) | VAF 24/96 reads (25%) | catalogued as COSV100122705, COSV100124486; called by muse, mutect2, varscan2
- NEMP1 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100272282; called by muse, mutect2, varscan2
- NEXMIF | c.1773G>T p.K591N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs1354407773, COSV99281684; called by muse, mutect2
- NFATC3 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV100285659; called by muse, mutect2, varscan2
- NHP2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV99200957; called by muse, mutect2, varscan2
- NIN | c.4249C>G p.Q1417E | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1433374641; called by muse, mutect2
- NKRF | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.324); catalogued as COSV100441849; called by muse, mutect2, varscan2
- NLGN3 | c.1576G>A p.E526K (on ENST00000358741 / NM_181303.2; = p.E506K on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100705020; called by muse, mutect2, varscan2
- NMBR | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as COSV99237492; called by muse, mutect2
- NME7 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as COSV100891150; called by muse, mutect2, varscan2
- NME8 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as COSV52250521; called by muse, mutect2, varscan2
- NOL10 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100630268; called by muse, mutect2, varscan2
- NOS3 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV99872085; called by muse, mutect2, varscan2
- NOTCH4 | c.3025G>A p.E1009K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1017602752, COSV66681038, COSV66682600; called by muse, mutect2
- NOXRED1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV100033203; called by muse, mutect2, varscan2
- NPAS2 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.093); catalogued as COSV100176854; called by muse, mutect2, varscan2
- NPM3 | c.342C>G p.F114L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as COSV100761951; called by muse, mutect2, varscan2
- NR3C2 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs776434075, COSV100678638; called by muse, mutect2, varscan2
- NRDC | c.2839G>C p.D947H | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV100703303, COSV100703793; called by muse, mutect2, varscan2
- NRK | c.4473G>C p.K1491N | Missense Mutation (SNP) | VAF 54/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99688994; called by muse, mutect2, varscan2
- NRL | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99393404, COSV99393705; called by muse, mutect2, varscan2
- NSD1 | c.5920G>A p.E1974K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100729757; called by muse, mutect2, varscan2
- NSD3 | c.3271G>A p.D1091N | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100395685; called by muse, mutect2, varscan2
- NSMCE3 | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV99723337; called by muse, mutect2, varscan2
- NTSR1 | c.726C>G p.F242L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100980708; called by muse, mutect2, varscan2
- NUGGC | c.1992G>C p.Q664H | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100429727; called by muse, mutect2, varscan2
- NUP153 | c.3934G>C p.A1312P | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV100020761; called by muse, mutect2, varscan2
- NUP205 | c.2611C>T p.Q871* | Nonsense Mutation (SNP) | VAF 12/232 reads (5%) | catalogued as COSV99607488; called by muse, mutect2
- NUTM1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as COSV60995406; called by muse, mutect2, varscan2
- NWD1 | c.2057C>G p.S686* | Nonsense Mutation (SNP) | VAF 18/90 reads (20%) | catalogued as COSV60337931; called by muse, varscan2
- NXNL1 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV100112044, COSV100112072; called by muse, mutect2, varscan2
- OGDH | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV56050811, COSV56057582, COSV99759536; called by muse, mutect2, varscan2
- OGT | c.1945G>C p.E649Q | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101035595; called by muse, mutect2, varscan2
- OOSP2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.169); catalogued as COSV99613612; called by muse, mutect2, varscan2
- OR10H5 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100454788; called by muse, mutect2, varscan2
- OR10K2 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.346); catalogued as COSV100149639; called by muse, mutect2, varscan2
- OR11H4 | c.19G>C p.D7H | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.159); catalogued as COSV59560541; called by muse, mutect2, varscan2
- OR2A12 | c.221C>G p.S74W | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs778662610, COSV101283149, COSV101283201; called by muse, mutect2, varscan2
- OR2AG1 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.291); catalogued as COSV100264968; called by muse, mutect2, varscan2
- OR2F1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101231330, COSV67331559, COSV67332142; called by muse, mutect2, varscan2
- OR2H2 | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100590004; called by muse, mutect2, varscan2
- OR2S2 | c.725G>C p.C242S | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100558707; called by muse, mutect2
- OR4B1 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.633); catalogued as COSV100535620, COSV58883397; called by muse, mutect2, varscan2
- OR52I1 | c.701C>G p.S234* | Nonsense Mutation (SNP) | VAF 28/124 reads (23%) | catalogued as COSV100331807; called by muse, mutect2, varscan2
- OR6C4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 12/102 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as COSV67793130; called by muse, mutect2, varscan2
- OR6K3 | c.539C>A p.S180Y (on ENST00000368146; = p.S164Y on NM_001005327.2) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100933882; called by muse, mutect2, varscan2
- OR7A5 | c.43C>A p.L15M | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV100457918; called by muse, mutect2, varscan2
- OR7G1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.654); catalogued as rs894541372, COSV53319519; called by muse, mutect2, varscan2
- OR8D2 | c.172C>G p.P58A | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100659087, COSV62488652; called by muse, mutect2, varscan2
- OR8G5 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.36); catalogued as COSV100422263, COSV100422627, COSV100422691; called by muse, mutect2, varscan2
- OXR1 | c.277C>T p.Q93* (on ENST00000442977 / NM_001198532.1; = p.Q92* on NM_018002.3) | Nonsense Mutation (SNP) | VAF 30/178 reads (17%) | catalogued as COSV100367686; called by muse, mutect2, varscan2
- OXSM | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.16); catalogued as COSV99772113; called by muse, mutect2, varscan2
- P2RY13 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99854446; called by muse, mutect2
- PAM | c.371G>T p.G124V | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99173797; called by muse, mutect2, varscan2
- PANK4 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as COSV101022546, COSV101022616; called by muse, mutect2
- PANK4 | c.9G>C p.E3D | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.899); catalogued as COSV101015647, COSV65830318; called by muse, mutect2, varscan2
- PARD3 | c.1242G>C p.Q414H | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100401891; called by muse, varscan2
- PBDC1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.195); catalogued as rs781911481, COSV64895871; called by muse, mutect2, varscan2
- PCDHB1 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.17); catalogued as rs1438180524, COSV100128137, COSV100128376; called by muse, mutect2, varscan2
- PCDHB15 | c.2287G>C p.D763H | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV51148512, COSV99179155; called by muse, mutect2, varscan2
- PCDHB2 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99523522; called by muse, mutect2, varscan2
- PCDHB9 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.037); catalogued as COSV53375579, COSV53380716; called by muse, mutect2, varscan2
- PCDHGA10 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99545741; called by muse, mutect2, varscan2
- PCDHGA12 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1402814836, COSV99342111; called by muse, mutect2, varscan2
- PCDHGB4 | c.2246C>A p.S749Y | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV99545738; called by muse, mutect2, varscan2
- PCDHGC3 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV99342115; called by muse, mutect2, varscan2
- PCNA | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100996254; called by muse, mutect2, varscan2
- PCNT | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV52451522, COSV99388173; called by mutect2, varscan2
- PCSK5 | c.3982G>T p.E1328* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV101377690; called by muse, mutect2
- PDE11A | c.2056C>G p.Q686E | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.114); catalogued as COSV99614542; called by muse, mutect2, varscan2
- PDE3A | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 7/67 reads (10%) | catalogued as COSV62968248; called by muse, mutect2, varscan2
- PDE4A | c.1614C>G p.I538M (on ENST00000380702 / NM_001111307.2; = p.I299M on NM_006202.3) | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53362013, COSV99535061; called by muse, mutect2, varscan2
- PDE5A | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.358); catalogued as COSV53347088, COSV53347671; called by muse, mutect2, varscan2
- PDE6B | c.1868C>T p.S623L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs368095904; called by muse, mutect2, varscan2
- PDIA5 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100299716; called by muse, mutect2, varscan2
- PDILT | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1567317411, COSV56701809; called by muse, mutect2, varscan2
- PEBP4 | c.471G>C p.Q157H | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99835434; called by muse, mutect2, varscan2
- PELP1 | c.684G>C p.L228F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.799); catalogued as COSV99343255, COSV99343312; called by muse, mutect2
- PER2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.601); catalogued as COSV99612470; called by muse, mutect2, varscan2
- PEX5 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs767347186, COSV99871252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGGT1B | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.087); catalogued as rs761868131, COSV99686037; called by muse, mutect2, varscan2
- PGM5 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV101123541; called by muse, mutect2, varscan2
- PIAS3 | c.690G>C p.K230N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100992752; called by muse, mutect2, varscan2
- PIH1D2 | c.595C>A p.H199N | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV99735581; called by muse, mutect2, varscan2
- PIK3C3 | c.1108C>T p.H370Y | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100011528; called by muse, mutect2
- PITPNM2 | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV99759580; called by muse, mutect2, varscan2
- PITX3 | c.752C>G p.S251C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as COSV100892836, COSV64174163; called by muse, mutect2, varscan2
- PITX3 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV100892837; called by muse, mutect2
- PITX3 | c.399C>G p.F133L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV100892838; called by muse, mutect2
- PKHD1L1 | c.11521C>T p.R3841* | Nonsense Mutation (SNP) | VAF 18/117 reads (15%) | catalogued as rs533623778, COSV101006746; called by muse, mutect2, varscan2
- PKN2 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 60/444 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60133389; called by muse, mutect2, varscan2
- PKNOX1 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99373087; called by muse, mutect2, varscan2
- PLA2G15 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99547350; called by muse, mutect2, varscan2
- PLA2G4A | c.1837G>C p.D613H | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100820699; called by muse, mutect2
- PLBD2 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99785488; called by muse, mutect2, varscan2
- PLCB3 | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99657697; called by muse, mutect2, varscan2
- PLCE1 | c.5357G>A p.R1786K | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1327628714, CM156516, COSV99596869; called by muse, mutect2, varscan2
- PLCH1 | c.4898C>G p.S1633C (on ENST00000340059 / NM_001130960.2; = p.S1625C on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100398088, COSV58195696; called by muse, mutect2, varscan2
- PLCH1 | c.3761C>T p.S1254L (on ENST00000340059 / NM_001130960.2; = p.S1246L on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.335); catalogued as rs1201415979, COSV100398089; called by muse, mutect2, varscan2
- PLCH1 | c.3590C>G p.S1197* (on ENST00000340059 / NM_001130960.2; = p.S1189* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/86 reads (12%) | catalogued as COSV100398091; called by muse, varscan2
- PLEKHH2 | c.1730C>G p.S577C | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.524); catalogued as COSV99175045; called by muse, mutect2, varscan2
- PLEKHH2 | c.3665C>T p.S1222L | Missense Mutation (SNP) | VAF 62/304 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV99175047; called by muse, mutect2, varscan2
- PLG | c.1833G>C p.L611F | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100369510; called by muse, mutect2, varscan2
- PLXNA2 | c.4015G>A p.E1339K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.848); catalogued as rs1472817684, COSV65440119; called by muse, mutect2, varscan2
- PLXNA4 | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV100326576, COSV58106517; called by muse, mutect2
- POGK | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.287); catalogued as COSV100902585; called by muse, mutect2, varscan2
- POLB | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 26/160 reads (16%) | catalogued as COSV99613398; called by muse, mutect2, varscan2
- POLE4 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 29/133 reads (22%) | catalogued as rs781678030, COSV99284423; called by muse, mutect2, varscan2
- POLR3C | c.1338G>C p.L446F | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100493091; called by muse, mutect2, varscan2
- POU3F3 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100796878; called by muse, mutect2, varscan2
- PPIG | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99644865; called by muse, mutect2, varscan2
- PPM1J | c.1475C>G p.S492C | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99588478; called by muse, mutect2, varscan2
- PPP1R3A | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.518); catalogued as COSV99494080; called by muse, mutect2, varscan2
- PPP1R3F | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV99278987; called by muse, mutect2, varscan2
- PPP2R3B | c.1050G>C p.K350N | Missense Mutation (SNP) | VAF 67/335 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as rs757683941, COSV101180782; called by muse, mutect2, varscan2
- PPP4R4 | c.1002G>C p.L334F | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as rs887040022, COSV58552822, COSV58554714; called by muse, mutect2, varscan2
- PPP4R4 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as COSV100428961; called by muse, mutect2, varscan2
- PPRC1 | c.3979C>T p.Q1327* | Nonsense Mutation (SNP) | VAF 13/72 reads (18%) | catalogued as COSV99532025; called by muse, mutect2, varscan2
- PRDM4 | c.2309C>G p.S770* | Nonsense Mutation (SNP) | VAF 30/120 reads (25%) | catalogued as COSV99946711; called by muse, mutect2, varscan2
- PREP | c.1717G>A p.D573N (on ENST00000369110; = p.D639N on NM_002726.5) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100964109; called by muse, mutect2, varscan2
- PREX1 | c.1455C>G p.F485L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100906752; called by muse, mutect2, varscan2
- PRICKLE2 | c.1945C>G p.L649V (on ENST00000295902; = p.L593V on NM_198859.4) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99897961; called by muse, mutect2, varscan2
- PRKAB2 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV54213467; called by muse, mutect2
- PRKCG | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV99669463; called by muse, mutect2, varscan2
- PRKDC | c.3658C>G p.L1220V | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV100042529; called by muse, mutect2, varscan2
- PRKDC | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as COSV100042531; called by muse, mutect2, varscan2
- PROS1 | c.1084C>T p.Q362* | Nonsense Mutation (SNP) | VAF 25/113 reads (22%) | catalogued as COSV101260783; called by muse, mutect2, varscan2
- PRRT3 | c.1840C>A p.L614M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV99926734; called by muse, mutect2, varscan2
- PRX | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.071); catalogued as rs1024162447, CM1311068, COSV99398015; called by muse, mutect2, varscan2
- PSD | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs199922239, COSV50041659; called by muse, mutect2, varscan2
- PSG6 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 80/477 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.578); catalogued as COSV51834855; called by muse, mutect2, varscan2
- PTCHD4 | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV59786302; called by muse, mutect2, varscan2
- PTPN4 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 39/239 reads (16%) | catalogued as COSV99751210; called by muse, mutect2, varscan2
- PTPRE | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99618917; called by muse, mutect2, varscan2
- PTPRF | c.5273C>G p.S1758C | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100741173; called by muse, mutect2, varscan2
- PTPRR | c.1498-1G>A p.X500_splice | Splice Site (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99318610; called by muse, mutect2, varscan2
- PTPRZ1 | c.1114G>A p.G372S | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465528794, COSV101099703, COSV101100744; called by muse, mutect2, varscan2
- PUS10 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.693); catalogued as COSV100369731; called by muse, mutect2, varscan2
- RAB8A | c.99C>G p.F33L | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV56292286, COSV56293459; called by muse, mutect2, varscan2
- RAP1A | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs749041743, COSV100712871; called by muse, mutect2, varscan2
- RAPGEF2 | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1483671053, COSV100031574; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, varscan2
- RASSF4 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.087); catalogued as COSV100024486; called by muse, mutect2, varscan2
- RBM25 | c.1282G>C p.D428H | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.276); catalogued as COSV99999008; called by muse, varscan2
- RBM38 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.404); catalogued as rs1224485122, COSV61134972; called by muse, mutect2, varscan2
- RBMS2 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 23/99 reads (23%) | catalogued as COSV100008659; called by muse, mutect2, varscan2
- RBMXL2 | c.1103C>A p.S368* | Nonsense Mutation (SNP) | VAF 18/105 reads (17%) | catalogued as COSV100182512, COSV100182572; called by muse, mutect2, varscan2
- RELN | c.7054G>A p.D2352N | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.25); catalogued as COSV100634726; called by muse, mutect2, varscan2
- RETSAT | c.1795C>G p.L599V | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99805793; called by muse, mutect2
- REV3L | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 13/132 reads (10%) | catalogued as COSV100725627; called by muse, mutect2, varscan2
- RHBDD1 | c.117C>G p.I39M | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100392167; called by muse, mutect2, varscan2
- RHBG | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99660024; called by muse, mutect2, varscan2
- RICTOR | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 49/270 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.57); catalogued as COSV99704683; called by muse, mutect2, varscan2
- RIN1 | c.1624C>G p.L542V | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.19); catalogued as COSV100254934; called by muse, mutect2, varscan2
- RLF | c.1436G>A p.C479Y | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65653308; called by muse, mutect2, varscan2
- RNASE12 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100250609; called by muse, mutect2, varscan2
- RNF213 | c.11465G>A p.R3822K | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.049); catalogued as COSV100301348; called by muse, mutect2
- RNH1 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs145455574; called by muse, mutect2, varscan2
- ROBO4 | c.2790C>A p.F930L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as COSV60625619; called by muse, mutect2, varscan2
- ROR2 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs746196217, COSV65219329; called by muse, mutect2, varscan2
- RPL5 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.315); catalogued as rs764649729, COSV59873485; called by muse, mutect2, varscan2
- RPL6 | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as COSV99176175; called by muse, mutect2, varscan2
- RPS6 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.485); catalogued as rs1233214248, COSV59547812; called by muse, mutect2
- RPUSD1 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.84); catalogued as rs752096465, COSV99135965; called by muse, mutect2, varscan2
- RWDD2A | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99392545; called by muse, mutect2, varscan2
- RXRG | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.77); catalogued as COSV100717820; called by muse, mutect2, varscan2
- RYR2 | c.4888C>T p.L1630F | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV63703063; called by muse, mutect2, varscan2
- SACS | c.12737C>G p.S4246* | Nonsense Mutation (SNP) | VAF 22/133 reads (17%) | catalogued as COSV101207679; called by muse, mutect2, varscan2
- SAMD9L | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as rs1360407915, COSV100561093, COSV59080206; called by muse, mutect2, varscan2
- SAMD9L | c.801G>C p.M267I | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.91); catalogued as COSV59082658, COSV59086865; called by muse, mutect2, varscan2
- SAXO1 | c.770C>G p.P257R | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754882464, COSV101000200; called by muse, mutect2, varscan2
- SCD | c.926C>G p.S309C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100948924; called by muse, mutect2, varscan2
- SCN11A | c.4540C>A p.L1514M | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100182362; called by muse, mutect2, varscan2
- SCN2A | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 43/275 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.217); catalogued as COSV99333195; called by muse, varscan2
- SDR16C5 | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.85); catalogued as COSV100374134; called by muse, mutect2, varscan2
- SEC23B | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 94/452 reads (21%) | catalogued as COSV99358053; called by muse, mutect2, varscan2
- SEMA3C | c.2225G>A p.R742K | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV99543764; called by muse, mutect2, varscan2
- SEMA3E | c.109C>T p.H37Y | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100319480; called by muse, mutect2, varscan2
- SENP2 | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 77/406 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV99958132; called by muse, mutect2, varscan2
- SEPTIN10 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.703); catalogued as COSV100454310; called by muse, mutect2, varscan2
- SEPTIN7 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.989); catalogued as COSV100621885; called by muse, mutect2, varscan2
- SFPQ | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV100599438; called by muse, mutect2, varscan2
- SH3KBP1 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.054); catalogued as COSV101115138, COSV65640592; called by muse, mutect2
- SH3PXD2A | c.2692G>A p.E898K (on ENST00000369774 / NM_001365079.1; = p.E870K on NM_014631.2) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as COSV100280423; called by muse, mutect2, varscan2
- SH3TC1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV55281574; called by muse, mutect2, varscan2
- SHCBP1L | c.924G>C p.E308D | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV100841080; called by muse, mutect2, varscan2
- SHQ1 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.001); catalogued as rs1327703320, COSV100345304; called by muse, mutect2, varscan2
- SHROOM4 | c.2968C>G p.H990D | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV99174440; called by muse, mutect2, varscan2
- SHROOM4 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99174446; called by muse, mutect2, varscan2
- SIGLEC5 | c.1143C>G p.F381L | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV99707544; called by muse, mutect2, varscan2
- SLC12A5 | c.1358C>A p.S453* (on ENST00000454036 / NM_001134771.2; = p.S430* on NM_020708.5) | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99716711; called by muse, mutect2
- SLC13A3 | c.179C>A p.S60* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99287199; called by mutect2, varscan2
- SLC25A6 | c.213G>T p.W71C | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1217044975, COSV101195497; called by muse, mutect2, varscan2
- SLC35A2 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99504531; called by muse, mutect2, varscan2
- SLC3A1 | c.393C>G p.F131L | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99577568; called by muse, mutect2
- SLC41A3 | c.1199C>A p.S400* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100259902, COSV100260012; called by muse, mutect2
- SLC7A6 | c.174G>C p.M58I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as COSV99546810; called by muse, mutect2, varscan2
- SLC8A3 | c.1201G>C p.D401H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100776347; called by muse, mutect2
- SLC8A3 | c.588G>C p.K196N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99052462; called by muse, mutect2, varscan2
- SLC9C2 | c.3223C>T p.Q1075* | Nonsense Mutation (SNP) | VAF 19/143 reads (13%) | catalogued as COSV100876980; called by muse, mutect2, varscan2
- SLC9C2 | c.2250C>G p.I750M | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs1405106198, COSV100876982; called by muse, mutect2, varscan2
- SMARCA5 | c.2629C>G p.P877A | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV51644496; called by muse, mutect2, varscan2
- SMARCD1 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV101202967; called by muse, mutect2, varscan2
- SMARCE1 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV52861673; called by muse, mutect2, varscan2
- SMC2 | c.1472G>C p.R491T | Missense Mutation (SNP) | VAF 48/213 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV99659597; called by muse, mutect2, varscan2
- SMG1 | c.3091C>T p.R1031* | Nonsense Mutation (SNP) | VAF 71/416 reads (17%) | catalogued as COSV101246733; called by muse, mutect2, varscan2
- SMG8 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV99959037; called by muse, mutect2, varscan2
- SMTN | c.2259G>C p.Q753H | Missense Mutation (SNP) | VAF 43/243 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100294871; called by muse, mutect2, varscan2
- SNED1 | c.1546G>C p.D516H | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100123334, COSV60033925; called by muse, mutect2, varscan2
- SOGA3 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408801665, COSV100847048; called by muse, mutect2, varscan2
- SP140 | c.546G>C p.L182F | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV100614024; called by muse, mutect2, varscan2
- SPAG17 | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV100310315; called by muse, mutect2, varscan2
- SPATA5 | c.1733G>A p.R578K | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.298); catalogued as COSV99916282; called by muse, mutect2, varscan2
- SPATS1 | c.129G>C p.E43D | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.16); catalogued as COSV99913623; called by muse, mutect2, varscan2
- SPECC1 | c.3151G>A p.D1051N | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs565518088, COSV99822722; called by muse, mutect2, varscan2
- SPECC1L | c.2653-1G>A p.X885_splice | Splice Site (SNP) | VAF 23/163 reads (14%) | catalogued as COSV100063151; called by muse, mutect2, varscan2
- SPEF2 | c.385C>G p.Q129E | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99214784; called by muse, mutect2, varscan2
- SPEN | c.7834C>T p.P2612S | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.034); catalogued as COSV65367927; called by muse, mutect2, varscan2
- SPEN | c.8542C>T p.Q2848* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV101005547; called by muse, mutect2, varscan2
540 further variants in this file (197 protein-altering or splice-affecting, 310 silent, 33 other) are not listed here.
